TCGA case TCGA-43-3394 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ce8612ab-3149-4a6a-b424-29c0c21c9b8b

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 52 years; Vital status: Dead; Days to death: 1,190 days (3.3 years).

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 52.9 years (19,310 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,190 days (3.3 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 154 days; Days to treatment end: 215 days; Number of cycles: 4; Treatment dose: 3,000 mg; Prescribed dose: 750; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 154 days; Days to treatment end: 222 days; Number of cycles: 8; Treatment dose: 20,800 mg; Prescribed dose: 2600; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 574 days (1.6 years); Days to treatment end: 581 days (1.6 years); Number of cycles: 2; Prescribed dose: 65; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Nab-paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 588 days (1.6 years); Days to treatment end: 616 days (1.7 years); Number of cycles: 5; Treatment dose: 1,000 mg; Prescribed dose: 200; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment start: 588 days (1.6 years); Days to treatment end: 636 days (1.7 years); Treatment dose: 6,600 cGy; Course number: 1; Number of fractions: 33; Treatment anatomic sites: Regional Site.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 54.4 years (19,862 days); Days to diagnosis: 552 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site.

Follow-up (8 entries)
- Days to follow up: 352 days; Disease response: Tumor Free.
- Days to follow up: 433 days (1.2 years); Disease response: Tumor Free.
- Day 552 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 822 days (2.3 years); Disease response: With Tumor.
- Days to follow up: 1,190 days (3.3 years); Disease response: With Tumor.
- Karnofsky performance status: 90; Timepoint: Post Adjuvant Therapy.
- ECOG performance status: 0; Timepoint: Other.
- ECOG performance status: 1; Timepoint: Adjuvant Therapy.

Other clinical attributes
- DLCO (% of predicted): 81; FEV1/FVC after bronchodilator (%): 60; FEV1/FVC before bronchodilator (%): 60; FEV1 after bronchodilator (% of reference): 50; FEV1 before bronchodilator (% of reference): 36.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 15; Tobacco smoking onset year: 1979.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-43-3394-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.9; Intermediate dimension: 0.9; Shortest dimension: 0.6.
  Slide TCGA-43-3394-01A-01-TS1: Section location: Top; Percent tumor cells: 82; Percent tumor nuclei: 80; Percent necrosis: 14; Percent stromal cells: 4; Percent lymphocyte infiltration: 1.
  Slide TCGA-43-3394-01A-01-BS1: Section location: Bottom; Percent tumor cells: 65; Percent tumor nuclei: 75; Percent normal cells: 20; Percent necrosis: 15; Percent lymphocyte infiltration: 5.
- Sample TCGA-43-3394-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-43-3394-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-43-3394-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 4.4; Intermediate dimension: 0.8; Shortest dimension: 0.8.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 2; Anatomic organ subdivision: L-Lower; KRAS gene analysis indicator: No; Pulmonary function test indicator: Yes.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Gemzar.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Regimen number: 2; Pharmaceutical therapy drug name: Taxotere; Therapy regimen: Recurrence.
- Drug treatment 4: Regimen number: 2; Pharmaceutical therapy drug name: Abraxane; Therapy regimen: Recurrence.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; Treatment outcome at TCGA followup: Stable Disease; Performance status timing: Post-Adjuvant Therapy.
- Follow-up form 3: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,190 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,190 days; disease-free interval: event (new tumor event after initially disease-free), 552 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 552 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-43-3394-01A-01D-1549-01): tumor purity 0.6, ploidy 3.4, whole-genome doublings 1.
